Gene-level copy-number profile of tumor specimen TCGA-96-A4JK-01A from TCGA case TCGA-96-A4JK, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,974 days).
Specimen TCGA-96-A4JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.723edcd5-d70a-4c8a-8ac5-ddc1916b0f8a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-96-A4JK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f9927e0-bb6a-46e8-b9a5-411373c8598e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 905; copy number 2: 1,127; copy number 3: 25,354; copy number 4: 3,743; copy number 5: 12,600; copy number 6: 8,119; copy number 7: 3,644; copy number 8: 385; copy number 9: 2,181; copy number 10: 789; copy number 11: 276; copy number 12: 240; copy number 13: 249; copy number 14: 165; copy number 16: 26; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-96-A4JK-01): tumor purity 0.5, ploidy 2.82, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,234,256–11,771,350, 8 genes (within-gene range 0–3): CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 7,956 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,321,479–153,726,353, 196 genes, copy number 7 (broad region; genes not listed).
- chr2:38,814–2,331,664, 40 genes, copy number 7 (within-gene range 5–7): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1.
- chr2:3,379,675–82,538,711, 1,327 genes, copy number 7–12 (broad region; genes not listed).
- chr2:139,982,684–140,221,485, 5 genes, copy number 8: RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,683,888, 3 genes, copy number 8: AC092156.1, MIR7157, COPRSP1.
- chr2:163,288,995–164,352,223, 3 genes, copy number 8 (within-gene range 4–8): RNU6-627P, FIGN, AC016766.1.
- chr2:172,423,807–177,223,958, 108 genes, copy number 8–12 (broad region; genes not listed).
- chr2:177,229,191–177,265,515, 3 genes, copy number 10: DNAJC19P5, MIR3128, AC079305.1.
- chr2:177,392,768–181,105,968, 54 genes, copy number 10: AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2, FKBP7, PLEKHA3, TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1, AC092640.1, CCDC141, RNU7-104P, RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1.
- chr2:212,911,003–213,284,205, 9 genes, copy number 7: AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr2:221,532,668–222,944,639, 24 genes, copy number 7–10 (within-gene range 3–10): TMEM256P2, AC079834.1, RPL23P5, AC068489.1, LLPHP3, HSPA9P1, RPL23AP28, PAX3, CCDC140, AC010980.1, CT75, Y_RNA, SGPP2, NANOGP2, RNU6-619P, GAPDHP49, FARSB, MOGAT1, RRAS2P2, AC104772.1, RPL31P17, ACSL3, ATG12P2, ACSL3-AS1.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 9–21 (broad region; genes not listed).
- chr4:183,099,257–183,765,721, 18 genes, copy number 7 (within-gene range 3–7): WWC2, WWC2-AS1, CLDN22, CLDN24, AC093844.1, AC112698.1, CDKN2AIP, VTI1BP2, AC107214.1, ING2, AC107214.2, RWDD4, RNU6-479P, TRAPPC11, RNU6-335P, RNU6-1053P, AC108477.2, AC108477.1.
- chr5:58,198–12,297,504, 243 genes, copy number 7–8 (broad region; genes not listed).
- chr6:89,177,504–89,638,749, 10 genes, copy number 7 (within-gene range 4–7): GABRR1, GABRR2, TUBB3P1, UBE2J1, RRAGD, NACAP7, ANKRD6, RN7SL11P, AL159174.1, LYRM2.
- chr7:39,545,646–39,708,120, 8 genes, copy number 9: AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2.
- chr7:79,452,877–85,636,344, 49 genes, copy number 7: MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1.
- chr8:88,032,011–104,256,094, 303 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:107,857,589–110,105,964, 29 genes, copy number 7: AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48.
- chr8:142,089,827–142,917,843, 32 genes, copy number 13: AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2.
- chr9:70,529,060–71,446,904, 1 gene, copy number 7 (within-gene range 6–7): TRPM3.
- chr9:70,809,975–75,724,575, 54 genes, copy number 7–9: MIR204, PIGUP1, RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1, AL355674.1, RORB-AS1, RORB, AL137018.1, TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1.
- chr9:76,611,376–87,847,314, 145 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr9:99,821,855–103,689,577, 50 genes, copy number 8–9: NR4A3, STX17, AL358937.1, ERP44, UPF3AP3, INVS, RN7SL75P, RPS2P35, AL137072.1, NANOGP5, TEX10, MSANTD3, MSANTD3-TMEFF1, TMEFF1, CAVIN4, RN7SKP87, ACTG1P19, AL162395.1, GAPDHP26, PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4, ARL2BPP7, RNU6-329P, AL442644.2, AL442644.1, LINC00587, ZYG11AP1, AL365396.1, CYLC2, AL589823.1, LINC01492, AL390962.1, RNA5SP291.
- chr11:65,444,458–74,498,533, 394 genes, copy number 9 (broad region; genes not listed).
- chr12:66,767–45,610,620, 956 genes, copy number 7–11 (broad region; genes not listed).
- chr13:72,782,133–73,016,461, 1 gene, copy number 7 (within-gene range 3–7): PIBF1.
- chr13:73,036,401–73,661,891, 9 genes, copy number 7 (within-gene range 3–7): PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393.
- chr14:22,040,594–40,390,547, 469 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:78,170,373–79,868,291, 1 gene, copy number 7 (within-gene range 6–7): NRXN3.
- chr14:78,695,321–86,401,285, 65 genes, copy number 7 (broad region; genes not listed).
- chr14:93,987,225–106,875,071, 623 genes, copy number 9–11 (broad region; genes not listed).
- chr15:19,878,555–35,238,197, 534 genes, copy number 10–12 (broad region; genes not listed).
- chr17:7,839,904–8,322,514, 43 genes, copy number 8 (within-gene range 2–8): KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4, CHD3, SCARNA21, RNF227, KCNAB3, AC104581.2, TRAPPC1, CNTROB, AC104581.1, GUCY2D, AC104581.3, ALOX15B, AC129492.2, ALOXE3P1, ALOX12B, AC129492.1, MIR4314, ALOXE3, HES7, PER1, MIR6883, AC129492.3, VAMP2, TMEM107, SNORD118, AC129492.4, MIR4521, BORCS6, AC129492.6, AC129492.5, AURKB, LINC00324, CTC1, PFAS, AC135178.6, SLC25A35, RANGRF, AC135178.7, ARHGEF15.
- chr17:59,841,266–59,950,574, 6 genes, copy number 10 (within-gene range 4–10): MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21.
- chr20:1,317,571–1,393,096, 1 gene, copy number 9 (within-gene range 3–9): AL136531.2.
- chr20:1,325,405–2,866,732, 56 genes, copy number 8–9: SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3, SIRPG, SIRPG-AS1, SIRPB3P, RN7SL561P, AL109809.3, AL109809.2, AL109809.4, CKAP2LP1, AL109809.1, AL117335.1, SIRPA, PDYN-AS1, PDYN, RPL7P2, STK35, AL359916.1, AL121899.3, AL121899.4, AL121899.1, AL121899.2, TGM3, TGM6, Y_RNA, SNRPB, AL049650.1, ZNF343, TMC2, NOP56, MIR1292, SNORD110, SNORA51, SNORD86, SNORD56, SNORD57, IDH3B, AL049712.1, EBF4, RPL19P1, CPXM1, AL035460.1, C20orf141, TMEM239, PCED1A, VPS16.
- chr20:7,069,614–23,990,454, 283 genes, copy number 8–14 (broad region; genes not listed).
- chr20:36,306,336–36,528,637, 1 gene, copy number 10 (within-gene range 3–11): DLGAP4.

Autosomal genes at a single copy (total copy number 1): 905. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
